CCDI case PBBXZD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/2a7a841b-0569-42c5-8efa-78d37bc5f788

Demographics
Sex at birth: female.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 11.9 years (4,356 days).

Biospecimens (3 samples)
- Sample 0DLRHG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLRHQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLRI1: Tissue type: Tumor; Specimen type: Solid Tissue.
